CPTAC case C3L-05338 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9515599a-b3f8-4a11-b9ae-ba2f2c291396

Demographics
Sex at birth: male; Race: white; Year of birth: 1973; Vital status: Dead; Days to death: 17 days; Year of death: 2019; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.0 years (16,793 days); Year of diagnosis: 2019; Days to last known disease status: 17 days; Progression or recurrence: no; Days to last follow up: 434 days (1.2 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (1 entry)
- Days to follow up: 434 days (1.2 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 90 kg; Height: 172 cm; BMI: 30.42.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 19; Cigarettes per day: 20; Tobacco smoking onset year: 1999; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 23; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (5 samples)
- Samples C3L-05338-51, C3L-05338-52, C3L-05338-53 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-05338-54, C3L-05338-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Time between excision and freezing: 215 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
